Somatic mutation profile of tumor specimen TCGA-DB-5275-01A (aliquot TCGA-DB-5275-01A-01D-1468-08) from TCGA case TCGA-DB-5275, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.6 years (13,371 days).
Specimen TCGA-DB-5275-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ab44460-0534-4fe8-b7d8-208498aa23cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5275-10A (Blood Derived Normal), aliquot TCGA-DB-5275-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e09bb47-7b93-45f7-addd-6d27c6c1d11c

The open-access MAF lists 40 somatic variants for this specimen: 37 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 25, Frame Shift Del 4, In Frame Del 3, Silent 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 53/149 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 87/106 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADPRM | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59379431; called by muse, mutect2, varscan2
- APBA2 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs765758239, COSV67104808; called by muse, mutect2, varscan2
- BBS12 | c.1810T>C p.Y604H | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV58562138; called by muse, mutect2
- CFAP54 | c.7609G>A p.A2537T | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100733450, COSV61572367; called by muse, mutect2, varscan2
- CPED1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 81/185 reads (44%) | catalogued as rs1024303974, COSV60002781; called by muse, mutect2, varscan2
- CTSV | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52344885; called by muse, mutect2, varscan2
- DNAH10 | c.10591G>A p.E3531K (on ENST00000409039; = p.E3470K on NM_207437.3) | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68994301; called by muse, mutect2
- FBN1 | c.2112A>G p.S704= | Splice Region (SNP) | VAF 45/131 reads (34%) | catalogued as COSV57317429; called by muse, mutect2, varscan2
- GLDC | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs1330595315, COSV58680312; called by muse, mutect2, varscan2
- ILVBL | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54619780; called by muse, mutect2
- KIFAP3 | c.618-2A>T p.X206_splice | Splice Site (SNP) | VAF 34/77 reads (44%) | catalogued as COSV63034075; called by muse, mutect2, varscan2
- MCHR2 | c.646T>C p.C216R | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV56003375; called by muse, mutect2, varscan2
- MTHFR | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.042); catalogued as COSV64877805; called by muse, mutect2
- PHC2 | c.1798_1800del p.K600del (on ENST00000257118 / NM_198040.2; = p.K65del on NM_004427.4) | In Frame Del (DEL) | VAF 112/344 reads (33%) | catalogued as rs759736840; called by pindel, varscan2
- PTPRC | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV61412069; called by muse, mutect2, varscan2
- RAD50 | c.2564A>G p.D855G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as rs751531030, COSV54751678; called by muse, mutect2, varscan2
- RDH8 | c.259G>A p.V87M (on ENST00000651512; = p.V67M on NM_015725.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545999307, COSV50674739; called by muse, mutect2, varscan2
- RGS13 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs529030881, COSV67345930; called by muse, mutect2, varscan2
- SETD5 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56711191, COSV56718374; called by muse, mutect2, varscan2
- SLC30A4 | c.1136-2A>T p.X379_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99970081; called by muse, mutect2
- SRP72 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756816276, COSV61377903; called by muse, mutect2, varscan2
- STYXL2 | c.3086C>A p.T1029N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs1340776254, COSV54805419; called by muse, mutect2, varscan2
- SULT1C3 | c.790T>C p.F264L | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61253102; called by muse, mutect2
- TBK1 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.726); catalogued as rs1400374794, COSV100538190, COSV59155379; called by muse, mutect2, varscan2
- TCIRG1 | c.1384_1386del p.N462del | In Frame Del (DEL) | VAF 27/316 reads (9%) | catalogued as rs771271907; called by mutect2, pindel
- UBN2 | c.4030C>T p.R1344W | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs961144676, COSV56030713; called by muse, mutect2, varscan2
- VPS13C | c.965G>T p.C322F (on ENST00000644861 / NM_020821.3; = p.C279F on NM_017684.5) | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV51186716; called by muse, mutect2, varscan2
- ZCCHC8 | c.2098C>G p.Q700E | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV60318349; called by muse, mutect2, varscan2
- API5 | c.782_783del p.Y261Ffs*3 | Frame Shift Del (DEL) | VAF 60/240 reads (25%) | called by pindel, varscan2
- ATRX | c.6339del p.F2113Lfs*10 | Frame Shift Del (DEL) | VAF 48/77 reads (62%) | called by mutect2, pindel, varscan2
- GRAMD1B | c.860_863del p.L287Hfs*44 | Frame Shift Del (DEL) | VAF 61/186 reads (33%) | called by mutect2, pindel, varscan2
- IGHV4-59 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 12/385 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2
- STK31 | c.392_410del p.P131Lfs*33 | Frame Shift Del (DEL) | VAF 38/158 reads (24%) | called by mutect2, pindel, varscan2
- USP21 | c.881_883del p.F294del | In Frame Del (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.2412T>C p.F804= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as COSV58567293; called by muse, mutect2
- MUC16 | c.17730T>G p.T5910= | Silent (SNP) | VAF 72/200 reads (36%) | catalogued as COSV67468268; called by muse, mutect2, varscan2
- NOS1 | c.465C>T p.P155= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as rs369224010; called by muse, mutect2, varscan2
